Somatic mutation profile of tumor specimen TCGA-95-8039-01A (aliquot TCGA-95-8039-01A-11D-2238-08) from TCGA case TCGA-95-8039, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.1 years (26,317 days).
Specimen TCGA-95-8039-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a9facde-8f8f-41b5-b4dd-928e7f6e31ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-8039-10A (Blood Derived Normal), aliquot TCGA-95-8039-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f5be210-1503-4a47-9b50-77ecc20ae7eb

The open-access MAF lists 103 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 23, Frame Shift Del 5, Nonsense Mutation 4, Splice Region 2, Intron 2, Splice Site 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.3692G>A p.R1231Q | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758069019, CM045702, COSV99793341; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 14/62 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACBD5 | c.306G>T p.W102C (on ENST00000375888 / NM_001352568.1; = p.W104C on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101022702; called by muse, mutect2, varscan2
- ACTRT1 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV100947786; called by muse, mutect2, varscan2
- ADAMTS14 | c.3299C>A p.P1100H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100941920; called by muse, mutect2, varscan2
- ANK2 | c.3331G>C p.D1111H | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100004611; called by muse, mutect2, varscan2
- ANKRD23 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs560056848, COSV100450574, COSV58412631; called by muse, mutect2, varscan2
- ARFGEF3 | c.4304A>G p.D1435G | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV99294882; called by muse, mutect2, varscan2
- BPTF | c.6506G>T p.G2169V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100076209; called by muse, mutect2, varscan2
- CCM2 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV99348211; called by muse, mutect2, varscan2
- CD86 | c.595G>A p.V199I (on ENST00000330540 / NM_175862.5; = p.V193I on NM_006889.4) | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.394); catalogued as rs747409361, COSV52608424; called by muse, mutect2, varscan2
- CDH10 | c.2081C>T p.T694M | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs543550761, COSV100051806, COSV52594816; called by muse, mutect2
- CDH12 | c.714A>T p.Q238H | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101203421; called by muse, mutect2, varscan2
- CHD9 | c.38A>G p.N13S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.237); catalogued as rs373677883; called by muse, mutect2, varscan2
- CUL7 | c.3665G>A p.R1222Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.718); catalogued as rs141899283; called by muse, mutect2, varscan2
- DNTT | c.552T>G p.N184K | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); catalogued as COSV100960788; called by muse, mutect2, varscan2
- DTD1 | c.100T>A p.S34T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV101080118; called by muse, mutect2, varscan2
- EN1 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV99727444; called by muse, mutect2, varscan2
- ESF1 | c.1150-1G>C p.X384_splice | Splice Site (SNP) | VAF 24/91 reads (26%) | catalogued as COSV99176561; called by muse, mutect2, varscan2
- FAM114A2 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV100697830; called by muse, mutect2, varscan2
- FKBP15 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV99440105; called by muse, mutect2, varscan2
- FRMD3 | c.1427A>G p.E476G | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as COSV100171109; called by muse, mutect2, varscan2
- FRY | c.6188C>T p.A2063V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs767093927, COSV100970018; called by muse, mutect2, varscan2
- FSIP2 | c.20329G>T p.E6777* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100556770; called by muse, mutect2, varscan2
- FYB1 | c.1875T>G p.Y625* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV100686549; called by muse, mutect2, varscan2
- GDF10 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs1361036100; called by muse, mutect2, varscan2
- GLI1 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57362001, COSV99954777; called by muse, mutect2, varscan2
- GPR18 | c.752G>C p.C251S | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.912); catalogued as COSV100540685; called by muse, mutect2, varscan2
- GPR39 | c.704T>G p.L235R | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100258762; called by muse, mutect2, varscan2
- HABP2 | c.264C>A p.C88* | Nonsense Mutation (SNP) | VAF 94/376 reads (25%) | catalogued as COSV100668118; called by muse, mutect2, varscan2
- HOXC12 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV54534983, COSV99678838; called by muse, mutect2
- KIRREL2 | c.1055A>C p.Q352P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.602); catalogued as COSV99384530; called by muse, mutect2, varscan2
- LAMA1 | c.5411A>T p.N1804I | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.659); catalogued as COSV101057940; called by muse, mutect2, varscan2
- LDB2 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.218); catalogued as COSV58761887, COSV58784552; called by muse, mutect2, varscan2
- LDLRAD1 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV62810051; called by muse, mutect2
- LMO7 | c.2690T>G p.V897G (on ENST00000357063; = p.V578G on NM_005358.5) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100412643, COSV100413946; called by muse, mutect2, varscan2
- LYST | c.10924A>C p.I3642L | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV101090433; called by muse, mutect2
- MARS1 | c.1483A>G p.I495V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV56252454; called by muse, mutect2, varscan2
- MB21D2 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV101165201, COSV66664691; called by muse, mutect2, varscan2
- MLX | c.826C>G p.H276D | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99519147; called by muse, mutect2, varscan2
- NAA15 | c.2155G>C p.A719P | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99649986; called by muse, mutect2, varscan2
- NAA15 | c.2155+1G>T p.X719_splice | Splice Site (SNP) | VAF 18/81 reads (22%) | catalogued as COSV56721716, COSV99649987; called by mutect2, varscan2
- NOTCH4 | c.3430G>C p.G1144R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100901167; called by muse, mutect2
- OLFML1 | c.782T>G p.V261G | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV100207117; called by muse, mutect2
- OR2M2 | c.1026G>C p.L342F | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100677304, COSV100677332; called by muse, mutect2, varscan2
- OR52A5 | c.835T>A p.L279M | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); catalogued as rs773485392, COSV100263592; called by muse, mutect2, varscan2
- PLEKHH3 | c.2302G>C p.D768H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.157); catalogued as COSV52218015, COSV99258083; called by muse, mutect2, varscan2
- PLK2 | c.1386C>T p.C462= | Splice Region (SNP) | VAF 21/124 reads (17%) | catalogued as rs756695967, COSV99956342; called by muse, mutect2, varscan2
- PPP1R13B | c.2782G>T p.A928S | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99163001; called by muse, varscan2
- PRMT3 | c.425T>G p.V142G | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as COSV100424297; called by muse, mutect2, varscan2
- PSMD3 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs1433149279, COSV99228123; called by muse, mutect2, varscan2
- RECQL5 | c.1303C>A p.Q435K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100512408; called by muse, mutect2, varscan2
- SBSN | c.1721C>A p.P574H (on ENST00000452271 / NM_001166034.2; = p.P231H on NM_198538.4) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1044834074, COSV101510117; called by muse, mutect2, varscan2
- SERPINB10 | c.828G>C p.W276C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99449802; called by muse, mutect2, varscan2
- SHANK1 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV99522208; called by muse, mutect2, varscan2
- SLC5A6 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV100143645; called by muse, mutect2, varscan2
- SPPL2A | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV55941596, COSV99961877; called by muse, mutect2, varscan2
- STK24 | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV100925044; called by muse, mutect2, varscan2
- SYBU | c.1490C>G p.P497R (on ENST00000276646 / NM_001099754.2; = p.P496R on NM_017786.6) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV99406742; called by muse, mutect2, varscan2
- TAS2R41 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 29/171 reads (17%) | catalogued as COSV101281509, COSV101281518; called by muse, mutect2, varscan2
- TBC1D9 | c.3020G>T p.W1007L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.564); catalogued as COSV101464319; called by muse, mutect2
- TCF7L1 | c.759A>C p.P253= | Splice Region (SNP) | VAF 36/140 reads (26%) | catalogued as COSV99964807; called by muse, varscan2
- TEX47 | c.189A>T p.K63N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV99787411; called by muse, mutect2, varscan2
- TRIM63 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs760601079, COSV100958209; called by muse, mutect2, varscan2
- UFSP2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV52990570, COSV99249394; called by muse, mutect2, varscan2
- UNC13C | c.1526A>C p.K509T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.023); catalogued as COSV99523823; called by muse, mutect2, varscan2
- VAV3 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV58391971; called by muse, mutect2, varscan2
- WNK1 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs770002621, COSV60029813; called by muse, mutect2, varscan2
- ZMAT1 | c.1881G>T p.E627D | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100858961; called by muse, mutect2, varscan2
- ZNF160 | c.1052G>C p.R351T | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as COSV100762505; called by muse, mutect2, varscan2
- ZNF512 | c.1599A>T p.E533D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100179482; called by muse, mutect2, varscan2
- AHR | c.2292_2329del p.C764* | Frame Shift Del (DEL) | VAF 42/320 reads (13%) | called by mutect2, pindel
- GPR18 | c.279del p.C94Afs*54 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- LRRC17 | c.1309del p.I437Lfs*3 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.2785_2786delinsC p.K929Qfs*15 | Frame Shift Del (DEL) | VAF 45/172 reads (26%) | called by pindel, varscan2*
- ZNF106 | c.3828del p.E1277Kfs*14 | Frame Shift Del (DEL) | VAF 27/98 reads (28%) | called by mutect2, pindel, varscan2
- ZNF365 | c.509_514del p.E170_A171del | In Frame Del (DEL) | VAF 28/150 reads (19%) | called by mutect2, pindel, varscan2
- ADRB2 | c.190C>T p.L64= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100019374; called by muse, mutect2, varscan2
- BCL2L1 | c.267G>A p.A89= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs749141019, COSV100304866; called by muse, mutect2, varscan2
- CCT3 | c.1479G>A p.L493= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99827543, COSV99827557; called by muse, mutect2, varscan2
- CD163L1 | c.405T>C p.H135= | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as COSV100550781; called by muse, mutect2, varscan2
- CDHR2 | c.300C>T p.S100= | Silent (SNP) | VAF 17/179 reads (9%) | catalogued as rs771021588, COSV99992262; called by muse, mutect2, varscan2
- DNAI1 | c.1614C>A p.A538= | Silent (SNP) | VAF 53/203 reads (26%) | catalogued as rs1201989652, COSV99647228; called by muse, mutect2, varscan2
- KCNAB2 | c.480G>T p.P160= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV51236826, COSV99379652; called by muse, mutect2, varscan2
- KREMEN2 | c.312G>A p.E104= | Silent (SNP) | VAF 37/160 reads (23%) | catalogued as rs758609677, COSV99567052; called by muse, mutect2, varscan2
- NEB | c.8028G>A p.E2676= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV99416809; called by muse, mutect2, varscan2
- NID2 | c.897C>T p.S299= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs774696658, COSV99357388; called by muse, mutect2, varscan2
- NLGN1 | c.1095A>C p.I365= | Silent (SNP) | VAF 48/246 reads (20%) | catalogued as COSV100850329; called by muse, mutect2, varscan2
- OR6B1 | c.165G>T p.L55= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV101281677; called by muse, mutect2, varscan2
- P4HA2 | c.621A>T p.S207= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as COSV99387520; called by muse, mutect2, varscan2
- PPP1R14C | c.486G>A p.K162= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs375113380, COSV100745075; called by muse, mutect2, varscan2
- PRUNE2 | c.612A>C p.P204= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV100943370; called by muse, mutect2, varscan2
- QTRT1 | c.828C>T p.D276= | Silent (SNP) | VAF 78/435 reads (18%) | catalogued as COSV99139167; called by muse, mutect2, varscan2
- RPP30 | c.660G>A p.A220= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs959120504, COSV99520992, COSV99521058; called by muse, mutect2, varscan2
- RUNX1T1 | c.1308T>A p.P436= (on ENST00000265814 / NM_001198628.1; = p.P409= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/230 reads (17%) | catalogued as COSV99750999; called by muse, mutect2, varscan2
- SLC13A3 | c.1803C>A p.T601= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as rs751123456, COSV99287038, COSV99287418; called by muse, mutect2, varscan2
- SLC4A8 | c.1497G>T p.L499= | Silent (SNP) | VAF 35/196 reads (18%) | catalogued as COSV60653127; called by muse, mutect2, varscan2
- TOX2 | c.522C>A p.A174= (on ENST00000358131 / NM_001098798.2; = p.A123= on NM_032883.3) | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100364815; called by muse, mutect2, varscan2
- UGT2B4 | c.420A>G p.L140= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100522728; called by muse, mutect2, varscan2
- UMPS | c.150G>A p.L50= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99229387; called by muse, mutect2, varscan2
- NEDD4L | c.122+29808C>T | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99896837; called by muse, varscan2
- TRIM14 | c.*168C>G | 3'UTR (SNP) | VAF 60/256 reads (23%) | catalogued as COSV99271566; called by muse, mutect2, varscan2
- TTN | c.34264+5317T>A | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs766345490, COSV100633787; called by muse, mutect2
